Gene-level copy-number profile of tumor specimen TCGA-2G-AAM4-01A from TCGA case TCGA-2G-AAM4, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AAM4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.bd82a84f-11f3-46ec-bf9d-7404891d68fa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAM4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8ab594d7-2ec2-4c16-8266-8d9c5bbf113d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 51; copy number 2: 31,043; copy number 3: 24,253; copy number 4: 1,326; copy number 5: 2,290; copy number 8: 850.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAM4-01A-11D-A434-01): tumor purity 0.86, ploidy 2.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 850 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–34,249,958, 850 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 51. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
